Somatic mutation profile of tumor specimen TCGA-VN-A88I-01A (aliquot TCGA-VN-A88I-01A-11D-A34U-08) from TCGA case TCGA-VN-A88I, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.1 years (21,576 days).
Specimen TCGA-VN-A88I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e96a033-cffc-4edd-a345-cc522cd283de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VN-A88I-10A (Blood Derived Normal), aliquot TCGA-VN-A88I-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c34435a-c515-47f3-ba19-58c245881310

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 1, Intron 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLI1 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV99954758; called by muse, mutect2
- GNL1 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.194); catalogued as COSV64921350; called by muse, mutect2
- HDAC3 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV100539776; called by muse, mutect2, varscan2
- KDM5C | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV64763692; called by muse, mutect2
- MGA | c.2787C>G p.Y929* | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | catalogued as COSV99581777; called by muse, mutect2, varscan2
- NRG1 | c.1637G>A p.R546Q (on ENST00000405005 / NM_013964.5; = p.R551Q on NM_013956.5) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs141355195; called by muse, mutect2, varscan2
- PDS5A | c.23A>G p.K8R | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as COSV100337578; called by muse, mutect2
- TNRC6A | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); catalogued as COSV100170522, COSV59361060; called by muse, mutect2
- ZC3H13 | c.1767T>G p.N589K | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV99668983; called by muse, mutect2
- HFM1 | c.357C>T p.G119= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV99646931; called by muse, mutect2, varscan2
- SPACA9 | c.*1350C>T | 3'UTR (SNP) | VAF 23/366 reads (6%) | catalogued as rs2231412; called by muse, mutect2
- SV2C | c.581-21283A>G | Intron (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
